Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-B0BV, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-B0BV-TTM1-A (Metastatic).

[page 1 of 15]
Surg Path Final Report
* Final Report *

* Final Report *

SURG PATH FINAL REPORT

SURGICAL PATHOLOGY

Collected:

Accession:

Physician:

-112

PROCEDURE

Colonoscopy/Gastroscopy with biopsy.

HISTORY

Dysphagia and history of colon polyps. Gastroscopy showed a large fungating mass in the lower third of the esophagus which was two-thirds circumferential. The remainder of the exam was normal. Colonoscopy showed a 0.4 cm hepatic flexure polyp.

GROSS

A. "Esophageal mass." Multiple less than 0.1 to 0.3 cm bits. All processed - 1 cassette.

B. "Hepatic flexure polyp." Two bits up to 0.2 cm. All processed - 1 cassette.

DIAGNOSIS

ESOPHAGUS (DISTAL): INVASIVE WELL-DIFFERENTIATED ADENOCARCINOMA, INTESTINAL TYPE.

COLON (HEPATIC FLEXURE): TUBULAR ADENOMA.

Type: Surg Path Final Report
Date:
Status: Auth (verified)
Title: SURG PATH FINAL REPORT
Encounter info:
Contributor system:

Printed by:
Printed on:

[page 2 of 15]
* Final Report *

SURG PATH FINAL REPORT

SURGICAL PATHOLOGY

Collected: [REDACTED] +371
Accession: [REDACTED]
Physician: [REDACTED]

PROCEDURE

Partial hepatectomy and cholecystectomy.

HISTORY

Esophageal cancer.

GROSS

- A. "Round ligament." A 8.5 x 7.5 x 1.0 cm fragment of fatty tissue containing a segment of ligament. Sampled - 1 cassette.
- B. "Left lateral segment of liver." A 7.5 x 6.5 x 3.0 cm fragment of liver. A well circumscribed firm gray 4.0 x 3.0 x 2.5 cm mass is located 0.4 cm from the closest surgical margin of resection. No involvement of the liver capsule is identified. The surrounding liver tissue is unremarkable. Sampled - 3 cassettes.
- C. "Gallbladder."
Length and greatest diameter: 6.5 x 2.1 cm.
Serosa: Smooth.
Wall thickness: 0.2 cm.
Mucosa: Hyperemic and granular.
Cystic duct: Unremarkable.
Stones: None.
Lymph nodes: None.
Sampled - 1 cassette.

DIAGNOSIS

LIVER: METASTATIC ADENOCARCINOMA CONSISTENT WITH ESOPHAGEAL
PRIMARY. MARGINS FREE.
BACKGROUND LIVER WITH CHANGES ASSOCIATED WITH PROXIMITY TO
MASS, INCIDENTAL VON MEYENBURG COMPLEX. NO FIBROSIS.

GALLBLADDER: CHOLESTEROSIS.

ROUND LIGAMENT: NO SIGNIFICANT ABNORMALITY.

[page 3 of 15]
Surg Path Final Report
* Final Report *

Completed Action List:

* [Redacted]

Type:	Surg Path Final Report	+371
Date:	[Redacted]	
Status:	Auth (Verified)	
Title:	SURG PATH FINAL REPORT	
Encounter info:	[Redacted]	
Contributor system:	[Redacted]	

[page 4 of 15]
*** Final Report ***

SP 1ST ADDENDUM REPORT

SURGICAL PATHOLOGY

Collected: [REDACTED] +371
Accession: [REDACTED]
Physician: [REDACTED]

ADDENDUM REPORT

IMMUNOPEROXIDASE FOR HER-2/NEU ANTIGEN (Clone 4B5): NEGATIVE (0).
Length of fixation: N/A
Cold ischemia time: N/A
10% neutral buffered formalin-fixed, paraffin-embedded tissue.

PathVysion GI Results: ****NEGATIVE****

Ratio of average HER-2 signals/D17Z1 signals: 1.20
Total number of cells counted: 30
Total number of HER-2 signals: 48 (1.6 per cell)
Total number of D17Z1 signals: 40 (1.3 per cell)

BIOPSY SPECIMEN STAINING PATTERN:

Negative (0): No reactivity in any tumor cell
Negative (1+): Tumor cell cluster with faint or barely perceptible membranous reactivity irrespective of percentage of tumor cells stained
Equivocal (2+): Tumor cell cluster with weak to moderate complete, basolateral or lateral membranous reactivity irrespective of percentage of tumor cells stained
Positive (3+): Tumor cell cluster with strong complete, basolateral or lateral membranous reactivity irrespective of percentage of tumor cells stained

PathVysion FISH:

Positive- ratio >2.0
Negative - ratio <1.8
Equivocal - ratio between 1.8 - 2.0

Methodology and Intended Use:

[REDACTED] Abbott Molecular/Vysis, Inc) is designed to detect amplification of the HER-2/neu gene via fluorescence in situ hybridization (FISH) in formalin-fixed, paraffin-embedded human cancer tissue specimens.
This technique allows the visualization of specific nucleic acid

[page 5 of 15]
SP 1st Addendum Report

* Final Report *

sequences

within a cellular preparation. Specifically, DNA FISH involves the precise annealing of a single stranded, fluorescently labeled DNA probe to complementary target sequences. The hybridization of the probe with the cellular DNA is visible by direct detection using fluorescence microscopy.

The PathVysion probes (LSI and CEP 17) are fluorescently labeled nucleic

acid probes for use in in situ hybridization assays on formalin-fixed, paraffin-embedded tissue specimen slide/s. When hybridized and visualized, these probes provide information on chromosome copy numbers for chromosome ploidy enumeration, which yields a ratio of the HER-2/neu gene to chromosome 17 copy number.

H AND E stained slide(s) were evaluated by a [REDACTED] pathologist and deemed

adequate for HER-2/neu FISH analysis by evaluating the invasive tumor per ASCO/CAP guidelines. FISH Slide(s) were imaged via an Ikonoscooper as applicable, then evaluated by both a [REDACTED] cytotechnologist and a [REDACTED] pathologist.

This test is done using Analyte Specific Reagents (ASR). The performance

was determined by [REDACTED]; it has not been cleared or approved by the US Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. [REDACTED] is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Results from the PathVysion test are intended for use as an adjunct to

existing clinical and pathologic information, and aids in the assessment of patients for whom Herceptin (Trastuzumab) treatment is being considered.

The FDA has approved Herceptin (Trastuzumab) in combination with chemotherapy

(Cisplatin, plus either Capecitabine or 5-fluorouracil [5-FU]), for HER-2-positive metastatic cancer of the stomach or gastroesophageal junction, in men and women who have not received prior medicine for their metastatic disease.

Printed by:

Printed on:

[page 6 of 15]
SP 1st Addendum Report
* Final Report *

Type:	SP 1st Addendum Report	
Date:		+371
Status:	Auth (Verified)	
Title:	SP 1ST ADDENDUM REPORT	
Encounter info:		
Contributor system:		

Printed by:
Printed on:

[page 7 of 15]
CT Abd and Pelvis w Contrast
* Final Report *

*** Final Report ***

Reason For Exam
HX OF METISTATIC ESOPHAGIAL EVAL FOR RELAPSE

REPORT

CT OF THE CHEST, ABDOMEN AND PELVIS WITH CONTRAST +616

INDICATION: History of esophageal cancer, evaluate disease status.

TECHNIQUE: Routine chest, abdomen and pelvis CT after the administration of oral contrast and 100 mL of Isovue nonionic intravenous contrast.

COMPARISON: CT of the chest, abdomen and pelvis from +532

FINDINGS:

CHEST: Stable cluster of nodularity in the left lung apex on slice 18 of series 2 which is nonspecific but could be due to bronchiolitis or scarring.

No lung consolidation. New ground glass nodularity in then right upper lobe on slice of Trachea and mainstem bronchi are patent.

Status post esophagectomy with gastric pull-up.

Printed by:
Printed on:

[page 8 of 15]
No suspicious axillary, mediastinal, or hilar lymphadenopathy.

Right jugular venous Port-A-Cath with tip near superior cavoatrial junction.

ABDOMEN/PELVIS: Status post left lateral segmentectomy. There are several new liver masses appearing when compared to prior study. For example, there is a 1.4 cm mass in segment of the liver on slice . Near the inferior aspect of the junction of the right and left lobes of the liver, there are four additional masses, the largest of which measures 2.3 x 2.2 cm on slice . Again noted is a large subcapsular fluid collection along the anterior surface of the liver measuring 14.2 x 6.6 cm. This likely represents a postoperative biloma or seroma.

Spleen, adrenal glands and pancreas are normal. Kidneys are normal except for subcentimeter hypodense lesions which are too small to characterize but likely represent cysts.

No suspicious intraabdominal lymphadenopathy. No abdominal ascites. Urinary bladder appears unremarkable. No free fluid in the pelvis. No suspicious inguinal or pelvic lymphadenopathy.

Review of bone windows demonstrates no suspicious osseous lesions.

IMPRESSION:

1. There are 5 new liver masses appearing when compared to prior study from . These have imaging characteristics compatible with metastatic disease. The largest of these lesions measures 2.3 x 2.2 cm.
2. Large subcapsular fluid collection along the anterior liver which is unchanged and likely represents a postoperative biloma or seroma.
3. Stable cluster of subcentimeter nodules within the left upper lobe and new area of ground glass nodularity in the anterior right upper lobe. This is nonspecific but

[page 9 of 15]
CT Abd and Pelvis w Contrast
* Final Report *

is likely infectious/inflammatory in etiology, possibly even related to aspiration
pneumonitis given gastric pull-up. Attention can be paid on follow-up studies.

Type: CT Abd and Pelvis w Contrast
Date: [Redacted] +616
Status: Auth (Verified)
Title: CT Abd and Pelvis w Contrast
By: [Redacted]

Printed by: [Redacted]
Printed on: [Redacted]

[page 10 of 15]
CT Abd and Pelvis w Contrast
* Final Report *

Verified By:
Encounter info:

Printed by:
Printed on:

[page 11 of 15]
CT Abd and Pelvis w Contrast

* Final Report *

*** Final Report ***

Reason For Exam

HX OF ESOPHOGEAL CA RESTAGE

REPORT

CT CHEST WITH CONTRAST, CT ABDOMEN AND PELVIS WITH CONTRAST

CLINICAL INDICATION: Esophageal carcinoma, followup.

PROTOCOL: Routine chest, abdomen and pelvis CT after the administration of oral contrast and 110 mL of Isovue-300 nonionic intravenous contrast.

COMPARISON: +767

CT CHEST WITH CONTRAST:

FINDINGS: No axillary or intrathoracic lymphadenopathy. Status post esophagectomy with gastric pull through.

No evidence of pulmonary parenchymal infiltrate, pleural or pericardial effusion.

CT ABDOMEN AND PELVIS WITH CONTRAST:

FINDINGS: Persistent fluid collection is seen along the right subphrenic area similar to prior examination. Again, possibility includes a postoperative seroma/hematoma or biloma. Status post left hepatic lobar resection again noted. No evidence of hepatic abnormality. The spleen, pancreas, adrenal glands and both kidneys are normal aside from the presence of a small right renal cyst. There is no evidence of mesenteric or periaortic lymphadenopathy. Tiny free fluid is present in the pelvis. No evidence of pelvic or inguinal lymphadenopathy.

Printed by:

Printed on:

[page 12 of 15]
CT Abd and Pelvis w Contrast
* Final Report *

IMPRESSION: No metastatic lesion seen on CT of the chest, abdomen and pelvis. Persistent right subphrenic fluid collection similar to prior examination. Differential diagnosis as discussed above.

Type: CT Abd and Pelvis w Contrast +858
Date: [Redacted]
Status: Auth (Verified)
Title: CT Abd and Pelvis w Contrast
By: [Redacted]
Verified By: [Redacted]
Encounter info: [Redacted]

Printed by:
Printed on:

[page 13 of 15]
CT Abd and Pelvis w Contrast

* Final Report *

*** Final Report ***

Reason For Exam

ESOPHAGEAL FOLLOW UP

REPORT

CT Chest w Contrast, CT Abd and Pelvis w Contrast

COMPLETED DATE: [REDACTED] +2436

REASON FOR EXAM: ESOPHAGEAL FOLLOW UP

ADDITIONAL HISTORY PROVIDED BY CLINICAL TEAM: None Provided (accession [REDACTED])
RESTAGING HISTORY OF METASTATIC ESOPHAGEAL CANCER, EVAL FOR RELAPSE. RECENT HX OF PULM
NODULES (accession [REDACTED])

HISTORY OBTAINED BY THE TECHNOLOGIST: Follow up to esophageal cancer. Patient diagnosed
in [REDACTED]. History of radiation and chemo in [REDACTED] ~-73
~-112

SMOKING HISTORY: Do you or have you ever smoked? Not applicable. Packs per day? n/a Years
smoked? n/a Year quit? n/a

PROTOCOL: Routine chest, abdomen and pelvis CT performed. Routine chest, abdomen and
pelvis CT performed. Isodense oral contrast was used.
CT performed with dose optimization technique including an iterative reconstruction
algorithm.

IV CONTRAST: 100mLs Isovue 370

COMPARISON: CT of the chest, abdomen, and pelvis dated [REDACTED] +2245

FINDINGS:

CHEST:

LUNGS: In the superior segment of the right lower lobe on image [REDACTED] there is
a 5 mm nodule. Upon review of prior examination there is a questionable 3 mm nodule in
this region. No additional lung nodules. The central airways are patent.

AXILLA, MEDIASTINUM, AND HILA: No suspicious axillary, mediastinal, or hilar
lymphadenopathy.

HEART AND GREAT VESSELS: No pericardial effusion. Normal heart size. Right chest port
with catheter tip in the right atrium. Normal course and caliber of the thoracic aorta.

PLEURAL SPACES: No pneumothorax or pleural effusion.

MISCELLANEOUS: No aggressive osseous bone lesions. The visualized lower neck is
unremarkable. We demonstrate postsurgical changes consistent with esophagectomy with
intrathoracic stomach.

ABDOMEN AND PELVIS:

Printed by:

Printed on:

[page 14 of 15]
CT Abd and Pelvis w Contrast

* Final Report *

LIVER: Within limitation of postsurgical changes consistent with prior left hepatic resection. There is a tiny amount of fluid seen adjacent to the anterior superior right hepatic lobe which is stable compared to prior exam. No new liver lesions.

GALLBLADDER: Surgically absent.

PANCREAS: Normal.

SPLEEN: Normal.

ADRENALS: No mass or nodule.

KIDNEYS: Stable appearance of a cyst in the lower pole of the right kidney. The kidneys otherwise unremarkable. No renal hydronephrosis.

LYMPH NODES: No suspicious intra-abdominal lymphadenopathy. No suspicious inguinal or pelvic lymphadenopathy.

BOWEL: Post surgical changes consistent with prior esophagectomy with intrathoracic stomach. No dilated or thickened bowel loops. No evidence of an obstruction. No mesenteric free fluid or stranding. There is a small fat-containing periumbilical hernia. Surgical clips are again noted within the left mid anterior abdomen likely related to a prior jejunostomy tube.

PELVIC ORGANS: Normal.

MISCELLANEOUS: No aggressive osseous bone lesions.

IMPRESSION:

+2436

1. In the superior segment of the right lower lobe, there is a 5 mm nodule. There is a questionable 3 mm nodule in this region on prior examination dated [REDACTED]. This finding may represent metastatic disease, infectious/inflammatory process, or developing primary bronchogenic malignancy. This nodule is not amenable to percutaneous biopsy and is below the resolution of PET/CT. Continued attention to this finding is recommended on follow-up imaging. Consider short-term follow-up CT in 2-3 months.

2. No CT evidence of metastatic disease within the abdomen and pelvis.

3. Post surgical changes consistent with prior esophagectomy with gastric pull-through.

Signature Line

***** FINAL REPORT *****

Printed by:
Printed on:

Page 2 of 3
(Continued)

[page 15 of 15]
CT Abd and Pelvis w Contrast
* Final Report *

Type: CT Abd and Pelvis w Contrast
Date: [REDACTED] +2436
Status: Auth (Verified)
Title: CT Abd and Pelvis w Contrast
By: [REDACTED]
Verified By: [REDACTED]
Encounter info: [REDACTED]

Printed by:
Printed on:

Source: NCI Genomic Data Commons file 5c64ef94-c64b-40a8-990e-fcd29f8b7a4e (ER0441 ER-B0BV Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).